Somatic mutation profile of tumor specimen C3N-01086-04 (aliquot CPT0212410006) from CPTAC case C3N-01086, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G2.
Specimen C3N-01086-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e3ecbb1-26a7-4e4a-bbce-135402e7437d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01086-71 (Blood Derived Normal), aliquot CPT0212500002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9738804a-18da-4c7c-a72d-4098e0687c5f

The open-access MAF lists 64 somatic variants for this specimen: 39 protein-altering or splice-affecting, 13 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 13, Intron 8, Frame Shift Del 5, Nonsense Mutation 2, 5'UTR 2, In Frame Del 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.234T>G p.N78K | Missense Mutation (SNP) | VAF 67/507 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV56543909, COSV56546338, COSV56551448; called by muse, mutect2, varscan2
- BCR | c.1833del p.N612Mfs*11 | Frame Shift Del (DEL) | VAF 46/426 reads (11%) | catalogued as COSV100006542; called by mutect2, varscan2
- C16orf96 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770766977, COSV71472210; called by muse, mutect2, varscan2
- F5 | c.4042C>G p.L1348V | Missense Mutation (SNP) | VAF 41/394 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); catalogued as rs1485283798, COSV63124463; called by muse, mutect2, varscan2
- GPRIN2 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 10/165 reads (6%) | catalogued as COSV100966430; called by muse, mutect2
- KRT1 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 74/536 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs749682564; called by muse, mutect2, varscan2
- OR56A3 | c.212C>A p.S71Y | Missense Mutation (SNP) | VAF 37/295 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61569731, COSV61570064; called by muse, mutect2, varscan2
- PLEKHS1 | c.998A>G p.Y333C (on ENST00000369310 / NM_182601.1; = p.Y353C on NM_024889.5) | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs776304790; called by muse, mutect2, varscan2
- PM20D1 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs572366251, COSV65649294; called by muse, mutect2, varscan2
- PRKX | c.248C>A p.P83H | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.962); catalogued as COSV99468826; called by muse, mutect2, varscan2
- TBC1D14 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs113945913; called by muse, mutect2
- TET1 | c.1692G>A p.M564I | Missense Mutation (SNP) | VAF 27/251 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs781372537, COSV65385133; called by muse, mutect2, varscan2
- WSCD1 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 52/419 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377198405; called by muse, mutect2, varscan2
- ZNF461 | c.772T>G p.C258G | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.034); catalogued as rs778017840; called by muse, mutect2, varscan2
- CUL7 | c.3926G>A p.S1309N | Missense Mutation (SNP) | VAF 38/434 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2
- DCUN1D3 | c.645_646del p.N216Qfs*32 | Frame Shift Del (DEL) | VAF 39/389 reads (10%) | called by mutect2, pindel
- DST | c.18196A>C p.K6066Q (on ENST00000361203 / NM_001374722.1; = p.K3763Q on NM_015548.5) | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- FBF1 | c.468T>A p.Y156* (on ENST00000586717; = p.Y170* on NM_001319193.1) | Nonsense Mutation (SNP) | VAF 31/280 reads (11%) | called by muse, mutect2, varscan2
- HYAL3 | c.1128A>T p.E376D | Missense Mutation (SNP) | VAF 48/449 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IL13RA2 | c.727T>C p.Y243H | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- LNPEP | c.2702_2722del p.E901_W908delinsG | In Frame Del (DEL) | VAF 16/111 reads (14%) | called by mutect2, pindel
- LRRC74B | c.721_722del p.R241Gfs*9 | Frame Shift Del (DEL) | VAF 29/287 reads (10%) | called by mutect2, pindel, varscan2
- MARF1 | c.1528T>A p.C510S | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2
- MED16 | c.941A>C p.E314A | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); called by muse, mutect2
- NCAM2 | c.742G>T p.G248C | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PABPC1L | c.236G>A p.G79D | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- PAPOLB | c.623C>A p.T208N | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIK3R1 | c.1481T>G p.F494C (on ENST00000521381 / NM_181523.3; = p.F224C on NM_181504.4) | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- REPS2 | c.587C>A p.P196H | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCAF1 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- SLC12A1 | c.1624A>T p.N542Y | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- SPEM2 | c.1361G>A p.G454D | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- SRRM1 | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); called by muse, mutect2
- TET2 | c.5739_5751del p.L1914Kfs*32 | Frame Shift Del (DEL) | VAF 40/333 reads (12%) | called by mutect2, pindel
- TRIM29 | c.116A>G p.D39G | Missense Mutation (SNP) | VAF 52/398 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC31 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- USP28 | c.2803G>A p.G935R | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- VPS13A | c.3598del p.L1200Sfs*37 | Frame Shift Del (DEL) | VAF 20/163 reads (12%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.7670C>A p.T2557N | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- ACACA | c.117T>C p.D39= | Silent (SNP) | VAF 31/231 reads (13%) | called by muse, mutect2, varscan2
- AKR1C2 | c.519G>T p.L173= | Silent (SNP) | VAF 22/262 reads (8%) | called by muse, mutect2
- ATP8B3 | c.2739C>T p.R913= | Silent (SNP) | VAF 31/304 reads (10%) | called by muse, mutect2, varscan2
- CHD8 | c.4452G>C p.R1484= (on ENST00000646647 / NM_001170629.2; = p.R1205= on NM_020920.4) | Silent (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- FAT2 | c.3492A>G p.P1164= | Silent (SNP) | VAF 44/462 reads (10%) | called by muse, mutect2
- FILIP1 | c.531G>A p.R177= | Silent (SNP) | VAF 32/408 reads (8%) | called by muse, mutect2
- KCNJ13 | c.913C>A p.R305= | Silent (SNP) | VAF 28/252 reads (11%) | catalogued as COSV52085575; called by muse, mutect2, varscan2
- KCNMA1 | c.2310A>G p.Q770= (on ENST00000286628 / NM_001161352.2; = p.Q712= on NM_002247.4) | Silent (SNP) | VAF 64/514 reads (12%) | called by mutect2, varscan2
- KRT27 | c.330T>C p.A110= | Silent (SNP) | VAF 50/448 reads (11%) | called by muse, mutect2, varscan2
- LONP1 | c.2763C>T p.Y921= | Silent (SNP) | VAF 11/156 reads (7%) | catalogued as rs201860702; called by muse, mutect2
- MEOX1 | c.108C>T p.P36= | Silent (SNP) | VAF 17/144 reads (12%) | catalogued as COSV100233691; called by muse, mutect2, varscan2
- RADIL | c.249C>A p.A83= | Silent (SNP) | VAF 39/387 reads (10%) | called by muse, mutect2
- ZC3H11A | c.1182A>C p.G394= | Silent (SNP) | VAF 61/533 reads (11%) | called by muse, mutect2, varscan2
- DLG3 | c.1145+649C>T | Intron (SNP) | VAF 26/109 reads (24%) | catalogued as rs1255512751; called by muse, mutect2, varscan2
- IGFN1 | c.1242-1573C>A | Intron (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- IKZF1 | c.161-8364A>C | Intron (SNP) | VAF 33/266 reads (12%) | called by muse, mutect2, varscan2
- LCK | c.188-63C>A | Intron (SNP) | VAF 38/299 reads (13%) | called by muse, mutect2, varscan2
- LINC00552 | n.460C>A | RNA (SNP) | VAF 24/230 reads (10%) | called by mutect2, varscan2
- NARF | chr17:82458733 G>C | 5'Flank (SNP) | VAF 14/130 reads (11%) | called by muse, mutect2, varscan2
- NRXN2 | c.3403+5470G>A | Intron (SNP) | VAF 7/52 reads (13%) | called by mutect2, varscan2
- PTPN9 | c.-10T>C | 5'UTR (SNP) | VAF 6/52 reads (12%) | called by muse, varscan2
- SDCBP2 | c.225+149C>T | Intron (SNP) | VAF 32/319 reads (10%) | catalogued as rs561821364; called by muse, mutect2, varscan2
- SMOC1 | c.-38del | 5'UTR (DEL) | VAF 26/190 reads (14%) | called by mutect2, pindel, varscan2
- SYNE1 | c.24977-1812T>C | Intron (SNP) | VAF 54/448 reads (12%) | catalogued as rs1284270457; called by muse, mutect2, varscan2
- ZSCAN2 | c.407-4232C>T | Intron (SNP) | VAF 22/177 reads (12%) | called by muse, mutect2, varscan2
